Somatic mutation profile of tumor specimen MMRF_1773_1_BM_CD138pos (aliquot MMRF_1773_1_BM_CD138pos_T1_KBS5U_K11311) from MMRF case MMRF_1773, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.3 years (16,177 days).
Specimen MMRF_1773_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64c10fda-2ea0-47eb-9566-760cfdede7f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1773_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1773_1_PB_Whole_C2_KBS5U_K11312; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea49a50e-053f-41db-9126-7fa616ff0f58

The open-access MAF lists 66 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 3'UTR 16, Silent 9, Intron 7, 5'UTR 3, RNA 2, Translation Start Site 2, 5'Flank 2, Splice Region 1, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 87/211 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LATS2 | c.1431_1436dup p.P479_A480dup | In Frame Ins (INS) | VAF 4/10 reads (40%) | hotspot (GDC flag); catalogued as rs550642106, COSV66878166, COSV66880240; called by mutect2, varscan2
- ARHGAP24 | c.1448G>A p.R483H (on ENST00000395184 / NM_001025616.3; = p.R390H on NM_031305.3) | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs116009088, COSV99982248; called by muse, mutect2, varscan2
- GRAMD1B | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1207068677, COSV100454805, COSV59203800; called by muse, mutect2, varscan2
- HAS1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV55789980; called by muse, mutect2
- IGKV1-5 | c.156T>A p.S52R | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs572812920; called by muse, varscan2
- IGKV1-5 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs11546104; called by muse, varscan2
- IGKV1-5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); catalogued as rs772574976; called by mutect2, varscan2
- IGLL5 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as rs763474712, COSV73248991, COSV73251236, COSV73251304; called by muse, mutect2
- IGLV3-1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs61731683; called by muse, varscan2
- IGLV3-1 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs758216465; called by muse, varscan2
- LRP4 | c.4645C>T p.R1549W | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764949031, COSV66137224; called by muse, mutect2
- MYO1H | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV60443270; called by muse, mutect2, varscan2
- NOVA2 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 76/146 reads (52%) | catalogued as COSV54356604; called by muse, mutect2, varscan2
- PCDHA11 | c.1697C>G p.A566G | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV56510963; called by muse, mutect2
- ABCB1 | c.1224G>A p.K408= | Splice Region (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEND4 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL25A1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 159/378 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPS1 | c.2708C>T p.T903I | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX60L | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERVFRD-1 | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYH14 | c.2596_2597del p.R866Afs*3 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by pindel, varscan2
- PAGR1 | c.-18_25del | Translation Start Site (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel
- SLCO1A2 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLITRK6 | c.2366A>T p.H789L | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD52 | c.1212C>T p.L404= | Silent (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- CASKIN1 | c.39G>A p.A13= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs766817654; called by muse, mutect2, varscan2
- COL19A1 | c.960T>A p.A320= | Silent (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- CRYBG1 | c.180G>A p.L60= | Silent (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- FDX1 | c.528A>G p.Q176= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- ITPRIPL2 | c.1020C>T p.G340= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs1408689795; called by muse, mutect2, varscan2
- KRT84 | c.15C>T p.S5= | Silent (SNP) | VAF 49/72 reads (68%) | called by muse, mutect2, varscan2
- SKOR1 | c.1098C>T p.G366= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as COSV58244235; called by muse, mutect2, varscan2
- ZNF366 | c.597C>T p.S199= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- AC083899.1 | n.2802G>A | RNA (SNP) | VAF 9/15 reads (60%) | catalogued as rs1266245538; called by mutect2, varscan2
- AP000769.5 | chr11:65498494 C>T | 5'Flank (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021479 C>T | 5'Flank (SNP) | VAF 52/107 reads (49%) | catalogued as rs563689113, COSV55848997, COSV55852452; called by muse, mutect2, varscan2
- BPNT1 | c.*411C>T | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.-110C>A | 5'UTR (SNP) | VAF 87/145 reads (60%) | catalogued as rs1345002906; called by muse, mutect2, varscan2
- ELOA2 | c.*304A>G | 3'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- ERG | chr21:38381277 T>C | 3'Flank (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- LINC02740 | n.26T>A | RNA (SNP) | VAF 78/186 reads (42%) | called by muse, mutect2, varscan2
- LTB | c.208+41A>T | Intron (SNP) | VAF 72/163 reads (44%) | catalogued as rs545155588; called by muse, mutect2, varscan2
- LTB | c.163-41G>A | Intron (SNP) | VAF 151/345 reads (44%) | catalogued as rs4647183, COSV53001370; called by muse, mutect2, varscan2
- LTB | c.162+23G>A | Intron (SNP) | VAF 52/102 reads (51%) | catalogued as rs891248449; called by muse, mutect2, varscan2
- LZIC | c.433-69T>C | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- MYCBP | c.*541C>T | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- NAP1L3 | c.*19del | 3'UTR (DEL) | VAF 21/28 reads (75%) | called by mutect2, pindel, varscan2
- NDUFA4 | c.189+71C>T | Intron (SNP) | VAF 5/146 reads (3%) | called by muse, mutect2
- NRXN1 | c.*3279T>C | 3'UTR (SNP) | VAF 49/102 reads (48%) | catalogued as rs965699428; called by muse, mutect2, varscan2
- PLXNA4 | c.*2435G>A | 3'UTR (SNP) | VAF 57/138 reads (41%) | catalogued as rs1053428257; called by muse, mutect2, varscan2
- POLA2 | c.*620A>T | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- POU3F3 | c.*101C>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- PPA2 | c.*502T>C | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*1010G>C | 3'UTR (SNP) | VAF 31/66 reads (47%) | catalogued as rs1474615896; called by muse, mutect2, varscan2
- PTPN5 | c.1330-538T>A | Intron (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- RRP7A | c.*2033_*2035dup | 3'UTR (INS) | VAF 25/104 reads (24%) | called by mutect2, pindel, varscan2
- SEPTIN11 | c.953+70A>T | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- SGCZ | c.-317A>G | 5'UTR (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- SPHK2 | c.-44C>T | 5'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- SYT1 | c.*1284dup | 3'UTR (INS) | VAF 42/84 reads (50%) | catalogued as rs35581563; called by mutect2, varscan2
- TMPRSS11F | c.*490G>C | 3'UTR (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- WWC2 | c.*3336G>T | 3'UTR (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.*4853A>T | 3'UTR (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- ZNF717 | c.*336C>T | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
